MMRF case MMRF_2095 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/4dd2a6b7-c0ae-4796-943b-1b41dae75a53

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 84 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 84.6 years (30,912 days); ISS stage: II; Days to last known disease status: 905 days (2.5 years); Days to last follow up: 905 days (2.5 years).
   Treatment given: Therapeutic agents: Bortezomib + Melphalan + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -18 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 38.8 mg/dL; Immunoglobulin G 9.75 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 4.8 µg/mL; Lactate Dehydrogenase 3.68 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 219 ×10⁹/L; Creatinine 127 µmol/L; Blood Urea Nitrogen 13.2 mmol/L; Calcium 2.58 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL; Glucose 4.46 mmol/L; C-Reactive Protein 0.15 mg/dL.
- Day 91 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 18.5 mg/dL; Immunoglobulin G 9.42 g/L; Immunoglobulin A 0.59 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 3.05 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 117 µmol/L; Blood Urea Nitrogen 12.5 mmol/L; Calcium 2.65 mmol/L; Albumin 39 g/L; Total Protein 6.1 g/dL; Glucose 4.4 mmol/L.
- Day 176: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.57 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 11.7 mg/dL; Immunoglobulin G 8.35 g/L; Immunoglobulin A 0.59 g/L; Immunoglobulin M 0.31 g/L; Hemoglobin 7.44 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 140 ×10⁹/L; Creatinine 132 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.45 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 6.82 mmol/L.
- Day 274: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 18 mg/dL; Immunoglobulin G 9.31 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 0.29 g/L; Lactate Dehydrogenase 3.48 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 137 ×10⁹/L; Creatinine 113 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.38 mmol/L; Albumin 39 g/L; Total Protein 6.4 g/dL; Glucose 4.35 mmol/L.
- Day 365 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 16.3 mg/dL; Immunoglobulin G 7.51 g/L; Immunoglobulin A 0.56 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 3.73 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 101 ×10⁹/L; Creatinine 120 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 4.51 mmol/L.
- Day 463 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.48 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 28.6 mg/dL; Immunoglobulin G 9.31 g/L; Immunoglobulin A 0.75 g/L; Immunoglobulin M 0.42 g/L; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 12.9 mmol/L; Calcium 2.45 mmol/L; Albumin 41 g/L; Total Protein 6.6 g/dL; Glucose 5.01 mmol/L.
- Day 554 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 22.5 mg/dL; Immunoglobulin G 8.92 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.34 g/L; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 113 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 4.51 mmol/L.
- Day 638 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.86 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 23.3 mg/dL; Immunoglobulin G 9 g/L; Immunoglobulin A 0.72 g/L; Immunoglobulin M 0.4 g/L; Lactate Dehydrogenase 2.95 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 123 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.4 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 6 mmol/L.
- Day 730 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 28.8 mg/dL; Immunoglobulin G 7.19 g/L; Immunoglobulin A 0.69 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 4.35 µkat/L; Hemoglobin 5.58 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 132 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 6 g/dL; Glucose 4.68 mmol/L.
- Day 849 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 46.5 mg/dL; Immunoglobulin G 9.69 g/L; Immunoglobulin A 0.83 g/L; Immunoglobulin M 0.34 g/L; Lactate Dehydrogenase 3.98 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 125 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL; Glucose 4.35 mmol/L.
- Day 905 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.99 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 26.3 mg/dL; Immunoglobulin G 9.01 g/L; Immunoglobulin A 0.84 g/L; Immunoglobulin M 0.35 g/L; Lactate Dehydrogenase 5.53 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 107 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.23 mmol/L; Albumin 35 g/L; Total Protein 6.7 g/dL; Glucose 3.85 mmol/L.

Other clinical attributes
- Day -18: Weight: 66 kg; Height: 154 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Lymphoma; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Leukemia.
- Relative with cancer history: yes; Relationship type: Child; Relationship primary diagnosis: Lymphoma.

Biospecimens (3 samples)
- Sample MMRF_2095_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -18 days.
- Sample MMRF_2095_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -18 days.
- Sample MMRF_2095_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 554 days (1.5 years).
